Surgical pathology report (de-identified scan), TCGA case TCGA-B9-A69E, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-A69E-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Kidney, left, total nephrectomy

Histologic tumor type/subtype: papillary renal cell carcinoma,
type 2

Sarcomatoid features: not identified

Histologic grade (if applicable): Fuhrman nuclear grade 2 (of 4)

Tumor size: 8.0 x 7.2 x 7.0 cm (gross measurement)

Tumor focality: unifocal

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: microscopic tumor
invasion into but not through capsule

Gerota' s fascia: negative

Renal sinus: negative

Major veins (renal vein or segmental branches, IVC): positive,
microscopic

Ureter: negative

Venous (large vessel): positive, microscopic

Lymphatic (small vessel): negative

Histologic assessment of surgical margins:

Gerota' s fascia: negative

Renal vein: negative

Ureter: negative

Adrenal gland: not submitted

Lymph nodes: none submitted

Pathologic findings in non-neoplastic kidney: mild
arteriolonephrosclerosis

AJCC Pathologic Staging: pT3a pNx

This staging information is based on information available at
the time of this report, and is subject to change pending
clinical review and additional information.

ICD-O-3
Carcinoma papillary renal cell
Site: @ Kidney Nbs 2049
pT3a pNx
2016/11/3

[page 2 of 2]
Clinical History:

-year-old male with left renal mass.

Gross Description:

Received is one appropriately labeled container, additionally labeled "left kidney." It holds a 1,220 gram, 25 x 12.0 x 10.0 cm nephrectomy specimen. The perinephric fat is inked blue. Within the fat there is a 16.2 x 8.0 x 8.0 cm kidney. Within the lower pole there is an 8.0 x 7.2 x 7.0 cm tan/yellow/red firm, well circumscribed, variegated mass. The mass bulges the capsule, but does not grossly appear to invade through it. The majority of the mass is solid (90%) with the remaining 10% being cystic. The cysts are filled with dark brown liquid. There are no white myxoid areas grossly noted. The mass does not invade into the sinus fat or involve the pelvis. The remainder of the kidney parenchyma is red/brown with a distinct corticomedullary junction. The renal vein artery and ureter are all patent. The adrenal gland is not grossly identified.

Block summary:

- A1 - ureter, vein and artery margins, en face
- A2-A3 - mass with respect to capsule
- A4-A6 - additional sections of mass
- A7 - uninvolved kidney away from mass
- A8 - additional section of normal kidney away from mass

Tumor and normal are submitted to

Source: NCI Genomic Data Commons file 72795d07-590d-4b1e-9f32-4f83c99c3b59 (TCGA-B9-A69E.14022E87-15A4-415D-A62E-2A99DFB54687.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).